Somatic mutation profile of tumor specimen TARGET-10-PAPFIX-09A (aliquot TARGET-10-PAPFIX-09A-01D) from TARGET case TARGET-10-PAPFIX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (822 days).
Specimen TARGET-10-PAPFIX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5b5d3d6-0275-47c6-b835-054ec59fe151.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFIX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFIX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bcf9bc5-3064-480e-88ed-fa227b111354

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STXBP2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs765370350; called by muse, mutect2, varscan2
- AEBP1 | c.2116A>C p.N706H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYSLTR1 | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- OTOGL | c.5468C>G p.T1823R (on ENST00000547103; = p.T1814R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRDD3 | chr14:22449108 del CTGTGACTGGG | Missense Mutation (DEL) | VAF 16/45 reads (36%) | called by mutect2, varscan2*
- XBP1 | c.502_503insTCCT p.R168Ifs*220 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- SFTPA2 | c.135C>T p.D45= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs370764679, COSV100958881; called by muse, mutect2, varscan2
